Somatic mutation profile of tumor specimen ALCH-B3FM-TTP1-A (aliquot ALCH-B3FM-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B3FM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.8 years (28,409 days).
Specimen ALCH-B3FM-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94c0b874-05d3-4415-a3cd-64fe740b9a39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3FM-NB1-A (Blood Derived Normal), aliquot ALCH-B3FM-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0eeda400-4b87-4763-b39f-22448c1ec1f8

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Splice Region 2, Silent 2, Frame Shift Del 2, Intron 1, 5'UTR 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIRE | c.973C>G p.P325A | Missense Mutation (SNP) | VAF 55/263 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99381380; called by muse, mutect2, varscan2
- CACNA1E | c.5701C>T p.R1901C | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs199591744, COSV62394080; called by muse, mutect2, varscan2
- CHEK1 | c.-23C>G | Splice Region (SNP) | VAF 17/64 reads (27%) | catalogued as rs996765922; called by muse, mutect2, varscan2
- FOLR3 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as rs760787092; called by muse, mutect2, varscan2
- LAMP2 | c.758A>C p.N253T | Missense Mutation (SNP) | VAF 52/572 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439172573; called by muse, mutect2
- NLGN3 | c.826G>A p.G276R (on ENST00000358741 / NM_181303.2; = p.G256R on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100704775; called by muse, mutect2
- STAB1 | c.4856C>T p.P1619L | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs780976654; called by muse, mutect2, varscan2
- UGGT1 | c.2369A>G p.N790S | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as rs772064248; called by mutect2, varscan2
- ACIN1 | c.3412C>G p.Q1138E | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- ADAMTS20 | c.202T>C p.S68P | Missense Mutation (SNP) | VAF 58/307 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ANK3 | c.9470C>A p.S3157Y | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ATF7IP2 | c.134A>T p.N45I | Missense Mutation (SNP) | VAF 128/401 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLT1D1 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- GPC3 | c.1099T>C p.F367L | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- HHIP | c.1129del p.D377Mfs*9 | Frame Shift Del (DEL) | VAF 16/134 reads (12%) | called by mutect2, pindel
- NIN | c.4914del p.F1638Lfs*3 (on ENST00000382041 / NM_182946.1; = p.F925Lfs*3 on NM_016350.4) | Frame Shift Del (DEL) | VAF 62/426 reads (15%) | called by mutect2, pindel, varscan2
- PARD3B | c.2714T>C p.L905P (on ENST00000406610 / NM_001302769.2; = p.L836P on NM_057177.7) | Missense Mutation (SNP) | VAF 65/301 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- STUB1 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TADA1 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TANC1 | c.3812-4G>T | Splice Region (SNP) | VAF 43/179 reads (24%) | called by muse, mutect2, varscan2
- EVC2 | c.1806C>T p.L602= | Silent (SNP) | VAF 66/411 reads (16%) | catalogued as COSV60404354; called by muse, mutect2, varscan2
- ZNF598 | c.1119C>T p.P373= | Silent (SNP) | VAF 41/286 reads (14%) | catalogued as rs1438242316; called by muse, mutect2, varscan2
- C3orf33 | c.114+497C>T | Intron (SNP) | VAF 58/320 reads (18%) | catalogued as rs995140445; called by muse, mutect2, varscan2
- CALCR | c.-63C>T | 5'UTR (SNP) | VAF 45/173 reads (26%) | called by muse, mutect2, varscan2
- GAS8 | c.*1249_*1258del | 3'UTR (DEL) | VAF 40/290 reads (14%) | called by mutect2, pindel
- TMEM140 | chr7:135148006 C>G | 5'Flank (SNP) | VAF 40/257 reads (16%) | called by muse, mutect2, varscan2
